TCGA case TCGA-DX-A6B9 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cc891960-42a2-4d76-b93b-c2914c929154

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Leiomyosarcoma, NOS: ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.8; Tissue or organ of origin: Overlapping lesion of connective, subcutaneous and other soft tissues; Site of resection or biopsy: Overlapping lesion of connective, subcutaneous and other soft tissues; Classification of tumor: primary; Age at diagnosis: 45.3 years (16,561 days); Year of diagnosis: 2012; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6.5; Tumor length measurement: 15; Tumor width measurement: 11.5.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 10.2; Tumor width measurement: 7.6.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: No; Tumor depth descriptor: Deep.

Follow-up (3 entries)
- Days to follow up: 349 days; Disease response: Tumor Free.
- Days to follow up: 748 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 1,138 days (3.1 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A6B9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,070 mg.
  Slide TCGA-DX-A6B9-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A6B9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A6B9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Colon.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,138 days; disease-specific survival: no event (censored), 1,138 days; disease-free interval: no event (censored), 1,138 days; progression-free interval: no event (censored), 1,138 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A6B9-01A-12D-A32H-01): tumor purity 0.87, ploidy 1.88, whole-genome doublings 0.
